Gene-level copy-number profile of tumor specimen C3N-02234-01 from CPTAC case C3N-02234, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 67.8 years (24,754 days).
Specimen C3N-02234-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 49576d7e-3e6d-4719-96f5-0895491d9427.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-02234-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,715 have no estimate.
https://portal.gdc.cancer.gov/files/d5b43406-e8fc-4fce-acc5-043687ad86ef

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 13; copy number 1: 8,852; copy number 2: 40,993; copy number 3: 8,645; copy number 4: 367; copy number 5: 24; copy number 6: 13; copy number 12: 1.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:48,316,863–48,556,358, 7 genes (within-gene range 0–2): PPP1R26P1, AL392048.1, LPAR6, Metazoa_SRP, RCBTB2, AL157813.2, AL157813.1.
- chr22:47,259,366–47,261,007, 1 gene: Z83836.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 38 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:119,409,333–119,410,233, 1 gene, copy number 12: AC093752.3.
- chr8:123,563,070–124,171,522, 13 genes, copy number 6: AC090193.1, RN7SKP155, AC135166.1, KLHL38, ANXA13, FAM91A1, FER1L6, AC090753.1, FER1L6-AS1, AC100871.2, FER1L6-AS2, AC100871.1, ARF1P3.
- chr8:126,556,323–127,419,050, 1 gene, copy number 5 (within-gene range 4–5): PCAT1.
- chr8:127,072,694–128,564,679, 23 genes, copy number 5: CASC19, PRNCR1, AC020688.1, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, LINC00824.

Autosomal genes at a single copy (total copy number 1): 6,017. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
